Somatic mutation profile of tumor specimen TCGA-FG-A4MT-02A (aliquot TCGA-FG-A4MT-02A-11D-A29Q-08) from TCGA case TCGA-FG-A4MT, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Temporal lobe; Tumor grade: G2; Age at diagnosis: 27.6 years (10,082 days).
Specimen TCGA-FG-A4MT-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7e9e522-ca3d-4c29-a39c-8e8a97de981d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A4MT-10A (Blood Derived Normal), aliquot TCGA-FG-A4MT-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd7daa2d-c2b8-4cfe-9f1a-7755d3eeec55

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic; called by muse, varscan2
- ARHGAP5 | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs1474856372, COSV100565437; called by muse, mutect2
- DSP | c.4108A>T p.I1370F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV65792467; called by muse, mutect2, varscan2
- DUSP5 | c.835A>G p.M279V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV63645750; called by muse, mutect2, varscan2
- EMC3 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99793962; called by muse, mutect2
- GABBR2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99410262; called by muse, mutect2
- HELZ2 | c.3943A>G p.T1315A (on ENST00000467148 / NM_001037335.2; = p.T746A on NM_033405.3) | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV101427571; called by muse, mutect2
- INPP4B | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs200327044, COSV53722669; called by muse, mutect2, varscan2
- KMT2D | c.15803T>C p.I5268T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1051071277, COSV56434754; called by muse, mutect2, varscan2
- LAMA3 | c.3881G>A p.R1294Q | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs547742221, COSV58067667; called by muse, mutect2, varscan2
- MPPED1 | c.464A>G p.D155G | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68837978; called by muse, mutect2, varscan2
- MUC16 | c.7123A>G p.N2375D | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67462425; called by muse, mutect2
- OR6F1 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 42/144 reads (29%) | catalogued as rs375716782, COSV100129389; called by muse, mutect2, varscan2
- TRRAP | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs782009444, COSV62843436; called by muse, mutect2, varscan2
- TTN | c.42962C>T p.T14321I (on ENST00000591111; = p.T6897I on NM_003319.4) | Missense Mutation (SNP) | VAF 58/167 reads (35%) | PolyPhen probably damaging (0.976); catalogued as COSV60018509; called by muse, mutect2, varscan2
- ATRX | c.5819_5822del p.D1940Vfs*14 | Frame Shift Del (DEL) | VAF 109/424 reads (26%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.3855C>T p.V1285= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- ZNF503 | c.1374G>A p.A458= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV65307344; called by muse, mutect2, varscan2
